Somatic mutation profile of tumor specimen TARGET-10-PAPAPX-09A (aliquot TARGET-10-PAPAPX-09A-01D) from TARGET case TARGET-10-PAPAPX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,770 days).
Specimen TARGET-10-PAPAPX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cd65ab8-9dbf-4de4-a799-2b08e3335f9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAPX-14A (Bone Marrow Normal), aliquot TARGET-10-PAPAPX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89092d38-02e9-4bf3-bc74-83cce6fa7608

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, 3'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.3995C>T p.P1332L | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs200860702; called by muse, mutect2, varscan2
- ENO1 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.145); catalogued as rs1421601381; called by muse, mutect2, varscan2
- GABRG2 | c.752-6C>T | Splice Region (SNP) | VAF 71/147 reads (48%) | catalogued as rs199883385; called by muse, mutect2, varscan2
- TIA1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.296); catalogued as rs1485829059, COSV57008514; called by muse, mutect2, varscan2
- TMPRSS15 | c.2533A>G p.M845V | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs374368287; called by muse, mutect2, varscan2
- TRAPPC5 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100365420; called by muse, mutect2, varscan2
- CLU | c.936C>A p.D312E | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); called by muse, mutect2
- IGHV2-70D | chr14:106723571 GTGGTATCCGTGCAC>TCTTA | Missense Mutation (DEL) | VAF 29/90 reads (32%) | called by pindel, varscan2*
- LAMA1 | c.1177C>G p.P393A | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYZL2 | c.339C>T p.D113= (on ENST00000375318; = p.D67= on NM_183058.3) | Silent (SNP) | VAF 71/157 reads (45%) | catalogued as rs374503421; called by muse, mutect2, varscan2
- RIN1 | c.1935C>T p.A645= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as rs372225390; called by muse, mutect2, varscan2
- SLCO1C1 | c.981A>T p.T327= | Silent (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- ZFR2 | c.1767C>T p.D589= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs550704725; called by muse, varscan2
- GPD2 | c.*40G>A | 3'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- KLF7 | chr2:207167267 ins A | 5'Flank (INS) | VAF 28/73 reads (38%) | called by mutect2, pindel*, varscan2*
